Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA0B, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA0B-01A (Primary Tumor).

ICD-C-3
Seminoma NOS 9061/3
Site: Ovary NOS C62.9
3/3/14

Date of procurement:

Pathohistological diagnosis

Seminoma, left testicle

Description

A testicle, size 4.5x3.5x2.5 cm with 10 cm long funiculus was received. On the surface we find 4 cm long surgical cut with sutures. On the cut we see gray-white 3.5x2x2 cm tumor that covers two thirds of testicular parenchyma.

Histologically, the tumor is made of solid clusters of round cells with oval bright nuclei in which we see nucleolus and moderately abundant bright and pink cytoplasm and surrounding those seats we find connecting tissue containing abundant lymphocyte clusters. On microscope's one large visual field we find 1-2 mitosis.

The tumor is not present in rete testis nor in funiculus.

Source: NCI Genomic Data Commons file b6801bb6-3444-4b3a-9cec-4941c07782e5 (TCGA-ZM-AA0B.2469E63F-275E-4A1C-A391-CD15E71C409B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).